Gene-level copy-number profile of tumor specimen TCGA-DK-AA6S-01A from TCGA case TCGA-DK-AA6S, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 60.3 years (22,027 days).
Specimen TCGA-DK-AA6S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.18772485-6ce1-4e03-8594-3177916da538.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-AA6S-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/90dcaffb-dd5d-462c-8bf5-08d7a31b0140

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 2: 44; copy number 3: 13,158; copy number 4: 10,311; copy number 5: 5,907; copy number 6: 23,139; copy number 7: 4,305; copy number 8: 1,972; copy number 9: 107; copy number 10: 554; copy number 11: 1; copy number 12: 279.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-AA6S-01A-21D-A390-01): tumor purity 0.68, ploidy 1.78, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:68,189,876–68,301,821, 2 genes: LINC02219, PIK3R1.
- chr9:21,967,752–22,128,103, 6 genes (within-gene range 0–3): CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr10:67,884,656–68,075,301, 5 genes: SIRT1, HERC4, RPS3AP38, RN7SL220P, POU5F1P5.
- chr14:68,149,617–68,236,539, 2 genes: RN7SL706P, RN7SL108P.
- chr14:102,224,500–102,305,190, 1 gene (within-gene range 0–2): MOK.
- chr14:102,592,649–102,911,500, 6 genes (within-gene range 0–3): RCOR1, RPL23AP11, Y_RNA, AL132801.1, TRAF3, RNU6-1316P.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
